Somatic mutation profile of tumor specimen TCGA-CV-6938-01A (aliquot TCGA-CV-6938-01A-11D-1912-08) from TCGA case TCGA-CV-6938, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 87.1 years (31,825 days).
Specimen TCGA-CV-6938-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5983559-e092-48db-8b05-ebc0dde7933d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6938-10A (Blood Derived Normal), aliquot TCGA-CV-6938-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03b83c30-25c4-45ac-96e8-ab1d9257fd62

The open-access MAF lists 129 somatic variants for this specimen: 103 protein-altering or splice-affecting, 26 silent.
By variant classification: Missense Mutation 85, Silent 26, Nonsense Mutation 10, Frame Shift Del 4, Splice Site 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1603C>T p.R535* | Nonsense Mutation (SNP) | VAF 12/94 reads (13%) | hotspot (GDC flag); catalogued as rs886039332, CM1513480, COSV62715090; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 9/58 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as rs104894230, CM053284, CM081305, CM123157, COSV54236734, COSV54236774, COSV54238174; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SPTAN1 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1305659962, COSV63987573, COSV63988267; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AAMP | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99815531; called by muse, mutect2, varscan2
- ADAM15 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as rs895501050, COSV55127413; called by muse, mutect2
- ADAM7 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as rs777076478, COSV104385187, COSV51538085; called by muse, mutect2, varscan2
- ADAMTS14 | c.1013G>A p.W338* | Nonsense Mutation (SNP) | VAF 11/91 reads (12%) | catalogued as COSV100941207; called by muse, mutect2, varscan2
- ADGRV1 | c.12871T>C p.S4291P | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101315258; called by muse, mutect2
- AGT | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100794165; called by muse, mutect2, varscan2
- AHCTF1 | c.4769A>T p.Y1590F (on ENST00000366508; = p.Y1564F on NM_015446.5) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.274); catalogued as COSV100402904; called by muse, mutect2, varscan2
- ANTXR1 | c.1648A>G p.N550D | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV100361462; called by muse, varscan2
- ARRB1 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63574266; called by muse, mutect2, varscan2
- ASB4 | c.783G>C p.W261C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV100366983; called by muse, mutect2
- C2CD2L | c.1822G>T p.D608Y | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100370977; called by muse, mutect2
- CCDC183 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100565866, COSV62012207; called by muse, mutect2
- CD80 | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99958081; called by muse, mutect2, varscan2
- CDH10 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52603228; called by muse, mutect2
- CDH24 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489493621, COSV52973626; called by muse, mutect2, varscan2
- CDR1 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs866031062, COSV100983371, COSV65164031; called by muse, mutect2, varscan2
- CFAP251 | c.1255A>G p.I419V | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99995565; called by muse, mutect2, varscan2
- CNNM4 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV100998560; called by muse, mutect2, varscan2
- CNOT4 | c.2134C>T p.R712C (on ENST00000541284 / NM_001190850.1; = p.R638C on NM_013316.4) | Missense Mutation (SNP) | VAF 54/517 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs182908121, COSV64158535; called by muse, mutect2
- COL4A1 | c.3200G>A p.G1067E | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1513268, COSV65421431; called by muse, varscan2
- CTCF | c.1915C>T p.Q639* | Nonsense Mutation (SNP) | VAF 27/226 reads (12%) | catalogued as COSV50547814; called by muse, mutect2, varscan2
- DHDDS | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs148606976; called by muse, mutect2, varscan2
- DNAH7 | c.11795G>C p.G3932A | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100413188; called by muse, mutect2, varscan2
- DNAJC14 | c.881G>A p.W294* | Nonsense Mutation (SNP) | VAF 10/112 reads (9%) | catalogued as COSV100423480; called by muse, mutect2
- DST | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.821); catalogued as rs370358616; called by muse, mutect2, varscan2
- DYRK1A | c.1360G>C p.D454H | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100117263; called by muse, mutect2
- EBF1 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58197854; called by muse, mutect2, varscan2
- EDNRB | c.463T>A p.S155T (on ENST00000377211 / NM_001201397.1; = p.S65T on NM_000115.5) | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100526036; called by muse, mutect2
- EP300 | c.2842G>A p.E948K | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV99606927; called by muse, mutect2, varscan2
- EPHA1 | c.2863C>T p.Q955* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99313397; called by muse, mutect2, varscan2
- ERRFI1 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772503313, COSV101087885; called by muse, mutect2, varscan2
- GAS2L3 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as rs1036806330, COSV99902599; called by muse, mutect2
- GFI1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99647328; called by muse, mutect2, varscan2
- GINM1 | c.590G>A p.S197N | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.466); catalogued as COSV100805256; called by muse, mutect2
- GRB7 | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs754805637, COSV100485402, COSV58451280; called by muse, mutect2, varscan2
- GRM5 | c.775A>G p.K259E | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); catalogued as COSV100549481; called by mutect2, varscan2
- H1-5 | c.361C>G p.P121A | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100137595; called by muse, mutect2, varscan2
- H4C5 | c.181G>C p.V61L | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100747831; called by muse, mutect2
- HAVCR1 | c.437C>G p.T146R | Missense Mutation (SNP) | VAF 66/590 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV100207757; called by muse, mutect2, varscan2
- HK1 | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.228); catalogued as COSV53858224; called by muse, mutect2, varscan2
- IFT43 | c.11T>A p.L4* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99465380; called by muse, mutect2, varscan2
- IRF6 | c.379+1G>C p.X127_splice | Splice Site (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100883818; called by muse, mutect2, varscan2
- LAMP2 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV52353084; called by muse, mutect2, varscan2
- LCNL1 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); catalogued as COSV99811592; called by muse, mutect2
- LMO1 | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100230705; called by muse, mutect2
- LRP10 | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); catalogued as rs1234871117, COSV62078221; called by muse, mutect2, varscan2
- MAPKBP1 | c.3728G>A p.R1243Q (on ENST00000456763 / NM_001128608.2; = p.R1237Q on NM_014994.3) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs779228316, COSV52960987; called by muse, mutect2, varscan2
- MARK1 | c.1532C>T p.T511I | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV100856948; called by muse, mutect2, varscan2
- MEFV | c.1610+1G>A p.X537_splice | Splice Site (SNP) | VAF 4/55 reads (7%) | catalogued as COSV99560042; called by muse, mutect2
- METTL17 | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100068402; called by muse, mutect2
- MROH8 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371995323; called by muse, mutect2
- MRPS35 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99317256; called by mutect2, varscan2
- MUC16 | c.20651C>T p.T6884I | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.529); catalogued as COSV101197255; called by muse, mutect2, varscan2
- NAALAD2 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs1276773293, COSV100427894; called by muse, mutect2
- NANP | c.83T>A p.M28K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1201512555, COSV100504962; called by muse, mutect2
- NEFL | c.1240C>A p.Q414K | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.316); catalogued as rs1206026169, COSV99647757; called by muse, mutect2, varscan2
- NOTCH1 | c.3442del p.E1148Sfs*31 | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | catalogued as COSV53043355; called by mutect2, varscan2
- OR4C11 | c.193T>C p.S65P | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100155068, COSV100155576; called by muse, mutect2
- OSBPL10 | c.1867A>G p.T623A | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.042); catalogued as COSV101158675; called by muse, mutect2
- PABPC3 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as COSV99878820; called by muse, mutect2
- PCDHA9 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs781788388, COSV65324991; called by muse, mutect2
- PDGFRB | c.2259del p.M754Cfs*4 | Frame Shift Del (DEL) | VAF 13/78 reads (17%) | catalogued as COSV55802806; called by mutect2, pindel, varscan2
- PHC2 | c.2029G>A p.V677M (on ENST00000257118 / NM_198040.2; = p.V142M on NM_004427.4) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.145); catalogued as COSV99930569; called by muse, mutect2, varscan2
- PHLPP2 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs570581294, COSV62425003; called by muse, mutect2, varscan2
- PIK3C2B | c.4697A>T p.N1566I | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100915937; called by muse, mutect2, varscan2
- PIK3CG | c.1922G>C p.R641T | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224222532, COSV100782385; called by muse, mutect2
- PLEC | c.3256G>A p.E1086K (on ENST00000322810 / NM_201380.4; = p.E976K on NM_000445.5) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs372173655; called by muse, mutect2, varscan2
- PLPP7 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs774170989, COSV100952512; called by muse, mutect2, varscan2
- POLQ | c.3179C>T p.S1060F | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV51760512; called by muse, mutect2
- POTEA | c.370C>G p.Q124E | Missense Mutation (SNP) | VAF 5/127 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1468846188; called by muse, mutect2
- PRKDC | c.9277C>T p.Q3093* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100037711; called by muse, mutect2, varscan2
- PROM2 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as rs371378593; called by muse, mutect2, varscan2
- PTX4 | c.341G>A p.R114Q (on ENST00000447419 / NM_001328608.2; = p.R109Q on NM_001013658.1) | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as rs746933052, COSV53515379; called by muse, mutect2, varscan2
- RASAL1 | c.736A>G p.N246D | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV55656397; called by muse, mutect2
- RPRD1A | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV100035982; called by muse, mutect2
- RTP3 | c.37C>A p.Q13K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99946877; called by mutect2, varscan2
- SDK1 | c.1903A>T p.S635C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101268530; called by muse, mutect2, varscan2
- SGK2 | c.1236C>G p.F412L | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100414517; called by muse, mutect2, varscan2
- SLC22A10 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV100235418; called by muse, mutect2, varscan2
- SLC26A9 | c.632C>A p.A211D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100535844; called by muse, mutect2, varscan2
- SLITRK4 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100567431, COSV62023384; called by muse, mutect2, varscan2
- TCF12 | c.1812T>A p.C604* | Nonsense Mutation (SNP) | VAF 18/110 reads (16%) | catalogued as COSV99975418; called by muse, mutect2, varscan2
- TENM2 | c.4228G>A p.A1410T (on ENST00000518659 / NM_001122679.2; = p.A1171T on NM_001080428.3) | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101317423; called by muse, mutect2
- TM4SF5 | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV99564476, COSV99564724; called by muse, mutect2
- TOM1L2 | c.1396G>A p.E466K (on ENST00000379504 / NM_001350333.2; = p.E416K on NM_001033551.3) | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100540786; called by muse, mutect2
- TRPA1 | c.2234C>A p.A745D | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs777487376, COSV100082696; called by muse, mutect2
- TTN | c.45154G>A p.V15052I (on ENST00000591111; = p.V7628I on NM_003319.4) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | PolyPhen benign (0.134); catalogued as rs377141765; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT2B4 | c.1085T>C p.L362P | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100522102; called by mutect2, varscan2
- VASH2 | c.608G>A p.R203H (on ENST00000517399 / NM_001301056.2; = p.R159H on NM_024749.5) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs150945050; called by muse, mutect2, varscan2
- VCAN | c.3205G>A p.D1069N | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as rs377090663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13D | c.9974A>G p.Y3325C | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs952497839, COSV99165295; called by muse, mutect2, varscan2
- ZIC2 | c.926G>C p.R309P | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100891742, COSV66254913; called by muse, mutect2, varscan2
- ZNF835 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV73379351; called by muse, mutect2, varscan2
- ZPBP2 | c.277C>A p.Q93K (on ENST00000348931 / NM_199321.3; = p.Q71K on NM_198844.3) | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100818481; called by muse, mutect2
- KMT2B | c.3462del p.N1156Mfs*26 | Frame Shift Del (DEL) | VAF 14/100 reads (14%) | called by mutect2, pindel, varscan2
- MUC16 | c.104dup p.G36Rfs*7 | Frame Shift Ins (INS) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- NEUROD6 | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- PCBP2 | c.475_476del p.V159Qfs*62 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | called by pindel, varscan2
- TBCC | c.976dup p.R326Pfs*13 | Frame Shift Ins (INS) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- USP19 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGT | c.861G>A p.K287= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100794163; called by muse, mutect2, varscan2
- ALDOC | c.633T>C p.A211= | Silent (SNP) | VAF 19/217 reads (9%) | catalogued as COSV99256504; called by muse, mutect2
- ATF7IP2 | c.112C>T p.L38= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100202456; called by muse, mutect2, varscan2
- CA6 | c.561C>T p.I187= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV101077262; called by muse, mutect2, varscan2
- CHSY1 | c.987T>C p.H329= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as rs1410675205, COSV99573495; called by muse, mutect2
- CPB2 | c.1170C>T p.G390= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV99472860; called by muse, mutect2, varscan2
- DNAH3 | c.7995G>C p.L2665= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV54550926, COSV99764006; called by muse, mutect2
- ENAM | c.3123G>A p.E1041= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV101252814; called by muse, mutect2, varscan2
- GOLGA6L9 | c.324C>T p.L108= | Silent (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- HELZ2 | c.3057G>A p.T1019= (on ENST00000467148 / NM_001037335.2; = p.T450= on NM_033405.3) | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs778538016, COSV64410785; called by muse, mutect2, varscan2
- HTRA3 | c.1146C>G p.V382= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV100246106, COSV56471539; called by muse, mutect2, varscan2
- KLHL13 | c.1233C>G p.V411= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV99450679; called by muse, mutect2, varscan2
- KPNA5 | c.1344T>C p.L448= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as COSV100706020; called by muse, varscan2
- NUP153 | c.888C>G p.L296= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100019556; called by muse, mutect2, varscan2
- OLFML2B | c.1962G>A p.A654= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs189641777, COSV99667889; called by muse, mutect2, varscan2
- OR56B1 | c.510G>T p.V170= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as rs149260229, COSV100402483; called by muse, mutect2, varscan2
- PANX3 | c.507C>T p.S169= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as rs147550190; called by muse, mutect2, varscan2
- PCDHA11 | c.1539C>T p.S513= | Silent (SNP) | VAF 28/228 reads (12%) | catalogued as COSV56490236; called by muse, mutect2, varscan2
- PLXNA3 | c.858C>T p.G286= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs782513809, COSV100859771; called by muse, mutect2, varscan2
- PUS7L | c.534C>T p.A178= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV100786425; called by muse, mutect2, varscan2
- SEMA5B | c.1254C>T p.N418= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as COSV99530358; called by muse, mutect2, varscan2
- SNRPD3 | c.21T>A p.I7= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV99307413; called by muse, mutect2, varscan2
- SPACA3 | c.177T>A p.A59= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV99284069; called by muse, mutect2, varscan2
- SUSD2 | c.2013C>G p.L671= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100844107; called by muse, mutect2, varscan2
- TCHH | c.2436G>A p.P812= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV100914829; called by muse, mutect2
- USO1 | c.1743A>C p.L581= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV99362427; called by muse, mutect2, varscan2
